Somatic mutation profile of tumor specimen TCGA-GN-A26A-06A (aliquot TCGA-GN-A26A-06A-11D-A19A-08) from TCGA case TCGA-GN-A26A, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 65.5 years (23,906 days).
Specimen TCGA-GN-A26A-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b97b1d8-512b-478c-ae98-76d5520c862a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GN-A26A-10A (Blood Derived Normal), aliquot TCGA-GN-A26A-10A-01D-A19A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0c0b22a-b080-4024-983b-58a8d4cdecee

The open-access MAF lists 395 somatic variants for this specimen: 256 protein-altering or splice-affecting, 129 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 243, Silent 129, Nonsense Mutation 7, Splice Site 4, Intron 3, 5'UTR 3, Frame Shift Ins 2, RNA 2, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- A1CF | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV50957343, COSV51028098; called by muse, mutect2, varscan2
- ABCA9 | c.3914A>G p.K1305R | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as COSV60629044; called by muse, mutect2, varscan2
- ABHD15 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56196318; called by mutect2, varscan2
- ABI3 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1212824481, COSV56800079; called by muse, mutect2, varscan2
- ACAP2 | c.2275C>T p.Q759* | Nonsense Mutation (SNP) | VAF 11/76 reads (14%) | catalogued as COSV58754366; called by muse, mutect2, varscan2
- ACSL6 | c.118C>T p.L40F (on ENST00000379240; = p.L65F on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.275); catalogued as COSV57300029; called by muse, mutect2, varscan2
- ACTL8 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as rs886522728, COSV64861479, COSV64862066; called by muse, mutect2, varscan2
- ADAM33 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV62936195; called by muse, mutect2, varscan2
- ADAMTS13 | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV63022531; called by muse, mutect2, varscan2
- ADARB1 | c.907C>T p.Q303* | Nonsense Mutation (SNP) | VAF 14/82 reads (17%) | catalogued as COSV62346620; called by muse, mutect2, varscan2
- ADORA1 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.34); catalogued as COSV55143635; called by muse, mutect2, varscan2
- AHNAK2 | c.12700C>T p.P4234S | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1196393266, COSV60923794; called by muse, varscan2
- AKAP4 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs147442985, COSV62073813; called by muse, mutect2, varscan2
- ANKEF1 | c.1229C>T p.S410L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs1440335644, COSV65692535; called by muse, mutect2, varscan2
- AOC1 | c.1924G>A p.D642N | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.092); catalogued as rs868863253, COSV62868289; called by muse, mutect2, varscan2
- ARHGEF10L | c.2044-1G>A p.X682_splice | Splice Site (SNP) | VAF 18/48 reads (38%) | catalogued as COSV51437883; called by muse, mutect2, varscan2
- ART3 | c.264G>A p.M88I | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV61915112, COSV61916203; called by mutect2, varscan2
- ASTE1 | c.620T>C p.F207S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53909778; called by muse, mutect2, varscan2
- ATAD2 | c.2381G>A p.R794K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.593); catalogued as COSV54884884; called by muse, mutect2
- ATP8B3 | c.2737C>T p.R913C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746328376, COSV59546450; called by muse, mutect2, varscan2
- AZIN2 | c.1165G>C p.A389P | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV53859536, COSV53859589; called by muse, mutect2, varscan2
- BCAM | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 54/214 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54304059; called by muse, mutect2, varscan2
- BCAT1 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1216581001; called by muse, mutect2
- C1GALT1 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV56180059; called by muse, mutect2, varscan2
- C2orf42 | c.1025C>T p.S342L | Missense Mutation (SNP) | VAF 50/278 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as rs753559635, COSV52449458; called by muse, varscan2
- CARD6 | c.2921C>T p.S974F | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.135); catalogued as COSV54566103; called by muse, mutect2, varscan2
- CCDC125 | c.893C>T p.T298I | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV67288627; called by muse, mutect2, varscan2
- CCDC185 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs1218541956, COSV64821507; called by muse, mutect2, varscan2
- CCDC24 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as rs1304413443, COSV100746177, COSV62211665; called by muse, mutect2, varscan2
- CCDC6 | c.737G>A p.R246K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.208); catalogued as COSV54058923, COSV54061115; called by muse, mutect2, varscan2
- CDCP1 | c.2054G>A p.G685E | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs1317594843, COSV56107171; called by muse, mutect2, varscan2
- CDHR3 | c.2465G>A p.R822H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs532858563, COSV58420121; called by mutect2, varscan2
- CDK13 | c.3977G>A p.G1326E | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.118); catalogued as COSV51704249; called by muse, mutect2, varscan2
- CELF3 | c.1210G>C p.G404R | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51885116; called by muse, mutect2, varscan2
- CFAP43 | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV53379240; called by muse, mutect2, varscan2
- CFAP53 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs919163455, COSV68352555; called by muse, mutect2, varscan2
- CFAP65 | c.4702C>T p.P1568S | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.465); catalogued as rs763606830; called by muse, varscan2
- CHRM2 | c.1298G>A p.S433N | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57780137, COSV99062904; called by muse, mutect2, varscan2
- CLEC6A | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.705); catalogued as COSV65987924; called by muse, mutect2, varscan2
- CNTN1 | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61643446; called by muse, mutect2, varscan2
- CNTNAP2 | c.1384C>T p.R462C | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs769071764, COSV62144657; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP2 | c.1625G>A p.G542E | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs372532510; called by muse, mutect2, varscan2
- COL4A4 | c.2213C>T p.S738F | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.708); catalogued as COSV61634833; called by muse, mutect2, varscan2
- COL4A4 | c.1298G>A p.G433E | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1468186854, COSV61631309; called by muse, mutect2, varscan2
- CPAMD8 | c.1154C>T p.P385L (on ENST00000651564; = p.P338L on NM_015692.5) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV52237874; called by muse, mutect2, varscan2
- CRP | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 120/330 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV54814296; called by muse, mutect2, varscan2
- CUX2 | c.3788C>T p.S1263F | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55642373; called by muse, mutect2, varscan2
- CYP19A1 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53060722; called by muse, mutect2, varscan2
- DAXX | c.1210C>T p.H404Y | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.158); catalogued as COSV99802142; called by muse, mutect2, varscan2
- DCAF1 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.98); catalogued as rs782756660, COSV60045493; called by mutect2, varscan2
- DDX4 | c.813C>G p.Y271* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV61756464; called by muse, mutect2, varscan2
- DIS3L | c.2660G>A p.G887D (on ENST00000319212 / NM_001143688.3; = p.G804D on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56020646; called by muse, mutect2, varscan2
- DKK2 | c.677A>G p.E226G | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53401263; called by muse, mutect2, varscan2
- DLGAP3 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as COSV52394558, COSV52396271; called by muse, mutect2
- DNAAF3 | c.1498G>A p.G500R (on ENST00000524407 / NM_001256715.2; = p.G547R on NM_178837.4) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated, low confidence (0.68); PolyPhen probably damaging (1); catalogued as COSV61278702; called by muse, mutect2, varscan2
- DNAH7 | c.8548G>A p.D2850N | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.081); catalogued as COSV56777583; called by muse, mutect2, varscan2
- DNAH9 | c.9588G>A p.M3196I | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV52366666; called by muse, mutect2, varscan2
- DSC3 | c.2227G>A p.D743N | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs755736392, COSV64574480; called by muse, mutect2, varscan2
- DSCAM | c.2521G>A p.E841K | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.254); catalogued as rs1362972133, COSV68032726; called by muse, mutect2, varscan2
- DSCAML1 | c.3651G>A p.M1217I (on ENST00000321322; = p.M1157I on NM_020693.4) | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV58398626; called by muse, mutect2, varscan2
- DSG1 | c.1678G>A p.V560I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57138104; called by muse, mutect2, varscan2
- EDEM2 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV65713072; called by muse, mutect2, varscan2
- ELOA2 | c.1900C>T p.P634S | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.531); catalogued as COSV55304730; called by muse, mutect2, varscan2
- EXTL3 | c.1712G>A p.G571E | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV55039493; called by muse, mutect2, varscan2
- EYA4 | c.1735A>C p.I579L (on ENST00000531901 / NM_001301013.1; = p.I573L on NM_004100.5) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV62058119, COSV62058870; called by muse, mutect2, varscan2
- FAM117A | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53633213; called by muse, mutect2, varscan2
- FAM177B | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.66); catalogued as COSV62601646; called by muse, mutect2, varscan2
- FAM189B | c.925G>A p.G309S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV56946842; called by muse, mutect2, varscan2
- FBXO10 | c.2059C>T p.R687* | Nonsense Mutation (SNP) | VAF 20/31 reads (65%) | catalogued as rs777439446, COSV52834669; called by muse, mutect2, varscan2
- FBXO40 | c.1261G>A p.G421R | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57526318; called by muse, mutect2, varscan2
- FRS3 | c.1183G>A p.G395S | Missense Mutation (SNP) | VAF 51/78 reads (65%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.549); catalogued as rs750411279, COSV52485940; called by muse, mutect2, varscan2
- GABRE | c.1462T>G p.F488V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64820715; called by muse, mutect2, varscan2
- GALNT6 | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62542936; called by muse, mutect2, varscan2
- GK2 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62626209; called by muse, mutect2, varscan2
- GLA | c.516T>G p.C172W | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM051524, COSV54510199; called by muse, mutect2, varscan2
- GNPAT | c.1158G>T p.W386C | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as COSV100791736, COSV64154007; called by muse, mutect2, varscan2
- GPR171 | c.390T>G p.F130L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV56390440; called by muse, mutect2, varscan2
- GPR50 | c.238T>A p.Y80N | Missense Mutation (SNP) | VAF 44/311 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV54441607; called by mutect2, varscan2
- GSPT2 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV61214134; called by muse, mutect2, varscan2
- HERC2 | c.2447C>T p.S816F | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV55341374; called by muse, mutect2, varscan2
- HHAT | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781614202, COSV54805496; called by muse, mutect2, varscan2
- HHIPL2 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 264/812 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58563681; called by muse, mutect2, varscan2
- HMCN1 | c.5410C>T p.R1804W | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.863); catalogued as rs771121234, COSV54894518; called by muse, mutect2, varscan2
- IFI35 | c.838G>A p.V280I (on ENST00000415816 / NM_001330230.2; = p.V282I on NM_005533.5) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.07); catalogued as COSV55896790; called by muse, varscan2
- IGHV1-18 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.259); catalogued as rs782674363; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1427C>T p.P476L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100781795, COSV61171942; called by muse, mutect2, varscan2
- IL27RA | c.16G>A p.G6S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.039); catalogued as COSV54602240; called by muse, mutect2, varscan2
- INSL6 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.077); catalogued as rs1229810864, COSV67563292; called by muse, mutect2, varscan2
- ITGA8 | c.2151G>A p.M717I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.372); catalogued as COSV65224226; called by muse, mutect2, varscan2
- JAKMIP1 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV51540780; called by muse, mutect2, varscan2
- JPH3 | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs767533433, COSV52465531; called by muse, mutect2, varscan2
- JPT2 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV50189232; called by muse, mutect2, varscan2
- KCNJ15 | c.872G>A p.S291N | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV60811614; called by muse, mutect2, varscan2
- KLK6 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777841287, COSV100037817, COSV59565159; called by muse, varscan2
- KRT72 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV53375680, COSV99537355; called by mutect2, varscan2
- LAMA1 | c.6037G>A p.E2013K | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.355); catalogued as COSV67541581; called by muse, mutect2, varscan2
- LEXM | c.842T>G p.V281G | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV64023666; called by muse, mutect2, varscan2
- LIG4 | c.2561C>T p.S854F | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as COSV63597701, COSV63598094; called by muse, mutect2, varscan2
- LIPF | c.721C>T p.L241F | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.045); catalogued as rs371144320, COSV104381371; called by muse, mutect2, varscan2
- LONRF2 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66541748; called by muse, mutect2
- LRP2 | c.1510C>T p.L504F | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55566618; called by muse, mutect2, varscan2
- LRP5 | c.1966C>T p.H656Y | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.159); catalogued as COSV53721072; called by muse, mutect2, varscan2
- LRRC6 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as rs886062700, COSV51545636; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRC74A | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV53611501; called by mutect2, varscan2
- LRRK2 | c.880T>G p.F294V | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54164065; called by muse, mutect2
- MAGEC1 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV53570262; called by muse, mutect2, varscan2
- MAGEC1 | c.2537C>T p.S846F | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.831); catalogued as COSV53578371; called by muse, mutect2, varscan2
- MAGEE1 | c.1588C>T p.P530S | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV63911524; called by muse, mutect2, varscan2
- MAGT1 | c.404C>T p.S135L (on ENST00000618282 / NM_001367916.1; = p.S167L on NM_032121.5) | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs782379098, COSV63782674; called by muse, mutect2, varscan2
- MARCHF2 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.138); catalogued as COSV53104160; called by mutect2, varscan2
- MEOX2 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.223); catalogued as rs868107417, COSV56287712; called by muse, mutect2, varscan2
- MEP1A | c.1315C>T p.R439W | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs749426037, COSV57921830; called by muse, mutect2, varscan2
- MEX3A | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.992); catalogued as COSV68479062; called by muse, mutect2, varscan2
- MGAM | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV72075273; called by muse, mutect2, varscan2
- MGAM | c.4112G>A p.S1371N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as rs1440824754, COSV72075274; called by muse, mutect2, varscan2
- MINAR1 | c.1322C>T p.S441L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV59585343; called by muse, mutect2, varscan2
- MMS22L | c.3458C>T p.S1153F | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV51524556; called by muse, mutect2, varscan2
- MUC16 | c.20751G>A p.M6917I | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.009); catalogued as rs756802696, COSV67453508; called by muse, mutect2, varscan2
- MUC16 | c.13307C>T p.P4436L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.924); catalogued as rs1401249797, COSV67481968; called by muse, mutect2, varscan2
- MYCBPAP | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.523); catalogued as COSV60410308; called by muse, mutect2, varscan2
- MYH15 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56317512; called by muse, mutect2, varscan2
- MYH2 | c.3746G>A p.G1249E | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as rs1219331596, COSV55440054; called by muse, mutect2, varscan2
- MYLK2 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as COSV65659685; called by muse, mutect2
- MYOCD | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs758932814, COSV58497408; called by muse, mutect2, varscan2
- NBEA | c.566G>A p.S189N | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.954); catalogued as COSV59808878; called by muse, mutect2, varscan2
- NDST3 | c.2474G>A p.G825E | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56625814; called by muse, mutect2, varscan2
- NDUFS7 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as rs1052564692, CM165967, COSV52041035; called by muse, mutect2
- NEMF | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.09); catalogued as COSV53590055; called by muse, mutect2, varscan2
- NFATC4 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.145); catalogued as COSV51608325; called by muse, mutect2, varscan2
- NFKB1 | c.503G>A p.G168E (on ENST00000394820 / NM_001382627.1; = p.G169E on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV56959702; called by muse, varscan2
- NIPBL | c.3172G>A p.E1058K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); catalogued as COSV56960864; called by muse, mutect2, varscan2
- NISCH | c.2239C>T p.R747W | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs62256878, COSV61901045; called by muse, mutect2, varscan2
- NLRX1 | c.2240C>T p.P747L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV52707535; called by muse, mutect2, varscan2
- NPLOC4 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1286794905, COSV58617479; called by muse, mutect2, varscan2
- NPY5R | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58453210; called by muse, mutect2, varscan2
- NRAP | c.1264G>A p.G422R (on ENST00000359988 / NM_001322945.2; = p.G387R on NM_006175.4) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs768712263, COSV63492899; called by muse, mutect2, varscan2
- NTSR2 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs201037497, COSV60992150; called by muse, mutect2, varscan2
- OR13C8 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as COSV58611373; called by muse, mutect2, varscan2
- OR2T3 | c.773G>A p.G258D | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748209286, COSV62083128; called by muse, varscan2
- OR4A5 | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.5); catalogued as COSV60523615, COSV60523768; called by muse, mutect2, varscan2
- OR52J3 | c.604C>T p.L202F | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1291796968, COSV66747043, COSV66747539; called by muse, mutect2, varscan2
- OR52N2 | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.961); catalogued as COSV57677490; called by muse, mutect2, varscan2
- OR6C1 | c.789A>T p.K263N | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.019); catalogued as COSV65573805, COSV65574184; called by mutect2, varscan2
- OR6F1 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as rs267598479, COSV100129224, COSV57468921; called by muse, mutect2, varscan2
- OTOF | c.2605G>A p.D869N (on ENST00000272371 / NM_194248.3; = p.D122N on NM_004802.4) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.305); catalogued as COSV55513000; called by muse, mutect2
- P2RX5 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.268); catalogued as COSV56593298; called by mutect2, varscan2
- PANK4 | c.301A>C p.I101L | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV65867528; called by muse, mutect2, varscan2
- PARP3 | c.1424C>T p.T475I | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.146); catalogued as COSV67168117; called by muse, mutect2, varscan2
- PCDH11X | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53448153, COSV53491829; called by muse, mutect2, varscan2
- PCDH11X | c.2134C>T p.R712C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as rs747764993, COSV53491859, COSV99036094; called by mutect2, varscan2
- PCDHAC1 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as rs1179807732, COSV53836554; called by muse, mutect2, varscan2
- PCNT | c.7061G>A p.G2354E | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.033); catalogued as COSV64024748, COSV64031522; called by muse, mutect2, varscan2
- PHKA1 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as rs1271854811, COSV59809296; called by muse, mutect2, varscan2
- PHLDB2 | c.2146G>A p.D716N (on ENST00000393925 / NM_001134439.2; = p.D673N on NM_145753.2) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV67308023, COSV67315431; called by muse, mutect2, varscan2
- PIGR | c.197C>T p.T66I | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62903197; called by muse, mutect2, varscan2
- PLEKHA7 | c.2638C>T p.R880* | Nonsense Mutation (SNP) | VAF 26/67 reads (39%) | catalogued as COSV60580695; called by muse, mutect2, varscan2
- PLEKHS1 | c.808G>A p.E270K (on ENST00000369310 / NM_182601.1; = p.E276K on NM_024889.5) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.73); catalogued as COSV63056424; called by muse, mutect2, varscan2
- PPP1R36 | c.560A>G p.E187G | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as COSV53903399; called by muse, mutect2, varscan2
- PRPF8 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59264902; called by muse, mutect2, varscan2
- PRTG | c.1607C>T p.S536F | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66839645; called by muse, mutect2, varscan2
- PSG2 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV68884027; called by muse, mutect2, varscan2
- PSPC1 | c.1272G>A p.M424I | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.38); catalogued as COSV58889812; called by muse, mutect2, varscan2
- PTCHD3 | c.1715C>T p.S572F | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.222); catalogued as COSV71257174; called by muse, mutect2
- PTPN21 | c.1507C>T p.P503S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV60850693; called by muse, mutect2, varscan2
- PXYLP1 | c.1168G>A p.G390S | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs931336154, COSV53892740; called by muse, mutect2, varscan2
- R3HDM4 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.175); catalogued as rs1320648465, COSV64293428; called by muse, mutect2, varscan2
- RAB34 | c.556G>A p.V186M | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV56388036; called by muse, mutect2, varscan2
- RAG1 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV55027057; called by muse, mutect2, varscan2
- RELN | c.9874G>A p.G3292R | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV59024316; called by muse, mutect2, varscan2
- SCN3A | c.5215G>A p.G1739R | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51808563; called by muse, mutect2, varscan2
- SCN3A | c.3393+1G>A p.X1131_splice | Splice Site (SNP) | VAF 6/20 reads (30%) | catalogued as COSV51818934; called by mutect2, varscan2
- SERPINI2 | c.620A>T p.N207I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV52987999; called by muse, mutect2, varscan2
- SH2D4A | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.071); catalogued as COSV56124160; called by muse, mutect2, varscan2
- SHLD2 | c.368G>A p.C123Y | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as COSV53957482; called by mutect2, varscan2
- SLC12A6 | c.2495C>T p.A832V (on ENST00000354181 / NM_001365088.1; = p.A781V on NM_005135.2) | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as COSV51629311; called by muse, mutect2, varscan2
- SLC27A2 | c.1168-1G>A p.X390_splice | Splice Site (SNP) | VAF 8/20 reads (40%) | catalogued as COSV51061216; called by muse, mutect2, varscan2
- SLC8A3 | c.2090C>T p.S697F (on ENST00000381269 / NM_183002.3; = p.S695F on NM_033262.4) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53691526; called by muse, mutect2, varscan2
- SLIT2 | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV56561641; called by muse, mutect2, varscan2
- SLIT2 | c.3127G>A p.D1043N | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV56586904; called by muse, mutect2, varscan2
- SLITRK3 | c.2723C>T p.P908L | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV53850541; called by muse, mutect2, varscan2
- SNF8 | c.256T>C p.F86L | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as rs1460764269, COSV51727530; called by muse, mutect2, varscan2
- SPART | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62087312; called by muse, mutect2, varscan2
- SPG7 | c.1562C>T p.A521V (on ENST00000268704; = p.A528V on NM_003119.4) | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51953217; called by muse, mutect2, varscan2
- SPHKAP | c.1385C>T p.A462V | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV60889616; called by muse, mutect2, varscan2
- SPTBN2 | c.5875C>T p.R1959W | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as rs774111091, COSV59450207; called by muse, mutect2, varscan2
- SSH1 | c.2135C>T p.P712L | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as rs1047577138, COSV58458741; called by muse, mutect2
- SSH2 | c.808A>G p.I270V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.262); catalogued as COSV52177920; called by muse, mutect2, varscan2
- SSX5 | c.224G>A p.R75Q (on ENST00000347757 / NM_175723.1; = p.R116Q on NM_021015.4) | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs139280367, COSV61256036; called by muse, mutect2, varscan2
- ST6GAL2 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 27/138 reads (20%) | PolyPhen benign (0.001); catalogued as rs1422029942, COSV64529257; called by muse, mutect2, varscan2
- STAB2 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66344038; called by muse, mutect2, varscan2
- STK17B | c.152T>C p.I51T | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.055); catalogued as COSV55829567; called by muse, mutect2, varscan2
- STX2 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55435521; called by muse, varscan2
- SUCLG2 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56210013; called by muse, mutect2, varscan2
- SULT1C3 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as rs866697546, COSV61252236; called by muse, mutect2, varscan2
- TAF1A | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 125/383 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV61919367; called by muse, mutect2, varscan2
- TCF7 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.523); catalogued as COSV58658374; called by muse, mutect2, varscan2
- TCF7L2 | c.761C>T p.P254L (on ENST00000355995 / NM_001367943.1; = p.P231L on NM_030756.5) | Missense Mutation (SNP) | VAF 54/296 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV53346027; called by muse, mutect2, varscan2
- TLCD3B | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 44/139 reads (32%) | catalogued as COSV54227818; called by muse, mutect2, varscan2
- TMC2 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.681); catalogued as COSV62651837, COSV62656564; called by muse, mutect2, varscan2
- TMTC3 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs760191992, COSV57125499; called by muse, mutect2, varscan2
- TNXB | c.6079G>A p.E2027K (on ENST00000647633; = p.E1780K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 234/394 reads (59%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); catalogued as COSV64475564; called by muse, mutect2, varscan2
- TRAF2 | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56040268; called by muse, mutect2, varscan2
- TRAPPC9 | c.3433G>A p.E1145K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV66906520; called by muse, varscan2
- TRMT44 | c.1973C>T p.T658I | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as rs769717448, COSV67664574; called by muse, mutect2, varscan2
- TRPC7 | c.1796A>G p.N599S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.517); catalogued as COSV61457395; called by muse, mutect2, varscan2
- TRPM5 | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 76/174 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50171316; called by muse, mutect2, varscan2
- TSHZ1 | c.2389G>A p.A797T (on ENST00000580243 / NM_001308210.2; = p.A752T on NM_005786.6) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV59014426; called by mutect2, varscan2
- TSTD2 | c.214T>G p.F72V | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as rs751229435, COSV57847138; called by mutect2, varscan2
- TTN | c.91100G>A p.R30367K (on ENST00000591111; = p.R22943K on NM_003319.4) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | PolyPhen benign (0.122); catalogued as COSV60041408, COSV60240341; called by muse, mutect2, varscan2
- UGT3A1 | c.1369G>A p.G457S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.9); catalogued as rs1218554862, COSV57101252; called by muse, mutect2, varscan2
- UPP2 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs769385960, COSV50046498; called by muse, mutect2, varscan2
- UROC1 | c.1545C>A p.D515E | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as rs369284359; called by muse, mutect2, varscan2
- USP26 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV63708023; called by mutect2, varscan2
- VAV1 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.26); catalogued as COSV58388712; called by muse, mutect2, varscan2
- VIPAS39 | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV58940031, COSV58941332; called by muse, mutect2, varscan2
- VWA5A | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs201601409, COSV63707493; called by muse, mutect2, varscan2
- ZBED9 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as rs868838585, COSV71729671; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1756C>T p.R586W | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.762); catalogued as rs1476558388, COSV60158115; called by muse, mutect2, varscan2
- ZNF17 | c.383G>C p.S128T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as rs1286661343, COSV56922124; called by muse, mutect2, varscan2
- ZNF302 | c.881T>C p.I294T (on ENST00000627982; = p.I215T on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.06); catalogued as COSV71063813; called by muse, mutect2, varscan2
- ZNF32 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV65641858; called by muse, mutect2, varscan2
- ZNF555 | c.292A>G p.T98A | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV62073695; called by muse, mutect2
- ZNF81 | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as COSV58577700; called by mutect2, varscan2
- ZYX | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as rs773528813, COSV51974264; called by muse, mutect2, varscan2
- ZZZ3 | c.1142C>T p.S381L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs760746735, COSV66234684; called by muse, mutect2, varscan2
- AC004922.1 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- ARHGAP10 | c.847G>A p.G283S | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ARHGAP10 | c.848G>A p.G283D | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- BCAT1 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDH23 | c.7064T>G p.I2355S | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- CFAP65 | c.4703C>T p.P1568L | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- CLK2 | c.684dup p.M229Dfs*3 (on ENST00000368361 / NM_001294339.2; = p.M228Dfs*3 on NM_003993.4) | Frame Shift Ins (INS) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- CMTM4 | c.554dup p.N185Kfs*2 | Frame Shift Ins (INS) | VAF 6/20 reads (30%) | called by mutect2, pindel
- EZHIP | c.163T>C p.S55P | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FAT4 | c.6275C>T p.P2092L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, varscan2
- FXYD5 | c.383-25_400del p.X128_splice | Splice Site (DEL) | VAF 10/108 reads (9%) | called by mutect2, pindel
- FZR1 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- GDF10 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.084); called by muse, mutect2
- GDF2 | c.342G>A p.M114I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- GNA11 | c.511G>A p.G171S | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGHG3 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- MMP28 | c.299C>G p.A100G | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC2 | c.1181T>C p.V394A | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- NPLOC4 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2L3 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PPP6R2 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- PRAMEF18 | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 35/392 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PTPA | c.1015C>T p.P339S (on ENST00000337738 / NM_178001.2; = p.P304S on NM_021131.5) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SCARA5 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCN8A | c.2852C>T p.A951V | Missense Mutation (SNP) | VAF 81/206 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- SH3RF2 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.133); called by mutect2, varscan2
- SLC8A2 | c.2008A>G p.K670E | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, varscan2
- SSUH2 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- SUPT20HL2 | c.1991A>T p.Q664L | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- TELO2 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- AC004922.1 | c.1566C>T p.P522= | Silent (SNP) | VAF 26/89 reads (29%) | called by muse, mutect2, varscan2
- ACSBG2 | c.156C>T p.T52= | Silent (SNP) | VAF 25/143 reads (17%) | catalogued as COSV53126772; called by muse, mutect2, varscan2
- ADGRL1 | c.3306G>A p.K1102= (on ENST00000340736 / NM_001008701.3; = p.K1097= on NM_014921.5) | Silent (SNP) | VAF 38/123 reads (31%) | catalogued as COSV61565709, COSV61565992; called by muse, mutect2, varscan2
- AFF3 | c.2250G>A p.R750= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs1164701728, COSV57865849; called by muse, mutect2, varscan2
- ANKRD26 | c.3306C>T p.S1102= | Silent (SNP) | VAF 15/78 reads (19%) | called by muse, mutect2, varscan2
- ANO2 | c.2160G>A p.S720= (on ENST00000356134 / NM_001278597.3; = p.S724= on NM_001278596.3) | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as rs368141631; called by muse, mutect2, varscan2
- BNIP5 | c.1845C>T p.N615= | Silent (SNP) | VAF 78/127 reads (61%) | catalogued as COSV71325755; called by muse, mutect2, varscan2
- CACNA1G | c.477C>T p.I159= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs749835211, COSV61734064; called by mutect2, varscan2
- CACNA2D3 | c.2949G>A p.K983= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV55565980; called by muse, mutect2
- CATSPER1 | c.1323G>A p.R441= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as COSV56412616; called by muse, mutect2, varscan2
- CCDC27 | c.174G>A p.S58= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs773950223, COSV53899895; called by mutect2, varscan2
- CELSR1 | c.2748C>T p.A916= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV53089557; called by muse, mutect2, varscan2
- CGAS | c.849C>T p.I283= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV64808752; called by muse, mutect2, varscan2
- CHD5 | c.2847G>A p.R949= | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as COSV52421667; called by muse, mutect2, varscan2
- CHURC1 | c.216C>T p.S72= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs543831874, COSV63036554; called by muse, mutect2, varscan2
- CLC | c.363G>A p.V121= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV55685827; called by muse, mutect2, varscan2
- CNGB3 | c.816G>A p.Q272= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV60695174; called by muse, mutect2, varscan2
- CNOT1 | c.4566A>G p.R1522= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as COSV55320504; called by muse, mutect2, varscan2
- CRELD2 | c.384C>T p.C128= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV58208037; called by muse, mutect2, varscan2
- CSMD3 | c.1176G>A p.E392= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV52268088; called by muse, mutect2, varscan2
- DAXX | c.1209C>T p.S403= | Silent (SNP) | VAF 25/80 reads (31%) | called by muse, mutect2, varscan2
- DNAH3 | c.2056C>T p.L686= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV54540149; called by muse, mutect2, varscan2
- DNAH9 | c.11328C>T p.F3776= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV52366681; called by muse, mutect2, varscan2
- DNM2 | c.774C>T p.F258= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV58968612; called by muse, mutect2, varscan2
- DPP10 | c.1410C>T p.F470= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs1300398285, COSV59709307; called by mutect2, varscan2
- DUSP1 | c.426C>T p.P142= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs772564174, COSV53320819; called by mutect2, varscan2
- EDIL3 | c.888C>T p.L296= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV56895371; called by muse, mutect2, varscan2
- EPB41L4B | c.2061C>T p.L687= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as rs571679914, COSV63124316; called by muse, mutect2, varscan2
- EPHB1 | c.1770G>A p.G590= | Silent (SNP) | VAF 46/114 reads (40%) | catalogued as COSV67667582; called by muse, mutect2, varscan2
- FBN3 | c.7281C>T p.F2427= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs764522835, COSV54468276; called by muse, varscan2
- FBN3 | c.2151C>T p.A717= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV54468289; called by muse, mutect2, varscan2
- FLNC | c.1542G>A p.K514= | Silent (SNP) | VAF 29/100 reads (29%) | catalogued as rs763782008, COSV57952714, COSV57961388; called by muse, mutect2, varscan2
- FZR1 | c.546C>T p.P182= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs1410385702; called by mutect2, varscan2
- GCKR | c.885C>T p.I295= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as COSV53110211; called by muse, mutect2, varscan2
- GK | c.1606C>T p.L536= (on ENST00000427190 / NM_001205019.2; = p.L530= on NM_001128127.2) | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV66738164; called by muse, mutect2, varscan2
- GLIPR1 | c.288G>A p.L96= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV56990091; called by muse, mutect2, varscan2
- GNA11 | c.510G>A p.L170= | Silent (SNP) | VAF 32/87 reads (37%) | called by muse, mutect2, varscan2
- GPATCH8 | c.2595C>T p.S865= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV59196841; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1236C>T p.I412= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV56089929; called by muse, varscan2
- GUCY1A2 | c.969C>T p.F323= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV56496073; called by muse, mutect2
- HEXD | c.156G>A p.E52= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs375075827, COSV60065294; called by muse, mutect2, varscan2
- HSPB2 | c.441T>A p.P147= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as COSV57052170; called by muse, mutect2, varscan2
- HYDIN | c.7347C>T p.P2449= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs377043715; called by muse, mutect2, varscan2
- IGKV1-17 | c.222C>T p.S74= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs562761949; called by muse, mutect2, varscan2
- IL36A | c.417C>T p.I139= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV52083150, COSV99382181; called by muse, mutect2, varscan2
- INSYN2A | c.123G>A p.R41= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as COSV54752533; called by muse, mutect2, varscan2
- IRS1 | c.1848C>T p.S616= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV59338704; called by muse, mutect2, varscan2
- KCNH6 | c.252G>A p.Q84= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as rs754783360, COSV59006307; called by muse, mutect2, varscan2
- KCNK17 | c.402C>T p.I134= | Silent (SNP) | VAF 78/144 reads (54%) | catalogued as COSV64685251, COSV64686169; called by muse, mutect2, varscan2
- KIAA1210 | c.3417C>T p.F1139= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs200456428, COSV68179022; called by muse, mutect2, varscan2
- LRRC37B | c.2454C>T p.F818= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as COSV58953922; called by muse, mutect2, varscan2
- LRWD1 | c.906G>A p.P302= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs752220551, COSV52961639; called by muse, mutect2, varscan2
- MARCHF10 | c.432G>A p.R144= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV60889568; called by muse, mutect2, varscan2
- MTNR1A | c.858C>T p.F286= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV56157198; called by muse, mutect2, varscan2
- MUC2 | c.1182G>C p.V394= | Silent (SNP) | VAF 15/26 reads (58%) | called by muse, mutect2, varscan2
- MUTYH | c.219A>T p.V73= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV58344745; called by muse, mutect2, varscan2
- MYH15 | c.486G>A p.G162= | Silent (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- MYH4 | c.1101C>T p.F367= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV55123440; called by muse, mutect2, varscan2
- MYH8 | c.4332C>T p.A1444= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV101238168, COSV67970036; called by muse, mutect2, varscan2
- NID2 | c.3051C>T p.T1017= | Silent (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- NR1H2 | c.873C>T p.F291= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV53802043; called by muse, mutect2, varscan2
- NT5DC2 | c.855C>T p.P285= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs551059201, COSV100194904, COSV58740922; called by muse, mutect2, varscan2
- OLFML2B | c.1629G>A p.R543= | Silent (SNP) | VAF 25/185 reads (14%) | catalogued as COSV54198996; called by muse, mutect2, varscan2
- OR1G1 | c.261C>T p.I87= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV61030455; called by muse, mutect2, varscan2
- OR2A12 | c.552C>T p.F184= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs565722500, COSV68821111, COSV99065255; called by muse, mutect2, varscan2
- OR2A12 | c.823C>T p.L275= | Silent (SNP) | VAF 33/125 reads (26%) | catalogued as COSV68821800; called by muse, mutect2, varscan2
- PARP1 | c.1623C>T p.H541= | Silent (SNP) | VAF 23/137 reads (17%) | catalogued as COSV64691626; called by muse, mutect2, varscan2
- PC | c.1101C>T p.I367= | Silent (SNP) | VAF 23/43 reads (53%) | catalogued as COSV63082028; called by muse, mutect2, varscan2
- PCDH12 | c.2187C>T p.F729= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs748190222, COSV99186255; called by muse, mutect2, varscan2
- PCDHB1 | c.1536G>A p.G512= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV60632529; called by muse, mutect2, varscan2
- PCDHB2 | c.2151G>A p.R717= | Silent (SNP) | VAF 16/202 reads (8%) | catalogued as rs1554271683, COSV50606314; called by muse, mutect2
- PCDHB3 | c.645G>A p.L215= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs1392255404, COSV50606416; called by muse, mutect2, varscan2
- PCDHB3 | c.1167C>T p.L389= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs782718277, COSV50606523; called by muse, mutect2, varscan2
- PCDHGA3 | c.1047C>T p.I349= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV54001673; called by muse, mutect2, varscan2
- PCDHGA5 | c.1356C>T p.F452= | Silent (SNP) | VAF 44/127 reads (35%) | catalogued as COSV53956200; called by muse, mutect2, varscan2
- PCLO | c.8472C>T p.L2824= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs1455736345, COSV61655320; called by muse, mutect2, varscan2
- PHF7 | c.801G>A p.R267= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as COSV59981326; called by muse, mutect2, varscan2
- PHF8 | c.1623G>A p.E541= (on ENST00000357988 / NM_001184896.1; = p.E505= on NM_015107.3) | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV57685807; called by muse, mutect2, varscan2
- PLA2R1 | c.765G>A p.E255= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV51784119; called by muse, mutect2, varscan2
- PON3 | c.882C>T p.N294= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs201950740, COSV55700788, COSV99672604; called by muse, mutect2, varscan2
- PPP1R1B | c.507G>A p.L169= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as COSV54202763; called by muse, mutect2, varscan2
- PTPA | c.1014C>T p.F338= (on ENST00000337738 / NM_178001.2; = p.F303= on NM_021131.5) | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs754311515; called by muse, mutect2, varscan2
- PXYLP1 | c.1167G>A p.L389= | Silent (SNP) | VAF 24/145 reads (17%) | catalogued as rs1276076819; called by muse, mutect2, varscan2
- RAB40A | c.366C>T p.I122= | Silent (SNP) | VAF 12/62 reads (19%) | called by muse, mutect2, varscan2
- RAPGEF1 | c.2925G>A p.S975= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as rs200079854, COSV100940714; called by muse, mutect2, varscan2
- RASGRP1 | c.585G>A p.R195= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs1358543090, COSV60365142; called by muse, mutect2, varscan2
- RECQL5 | c.645C>T p.I215= | Silent (SNP) | VAF 94/273 reads (34%) | catalogued as rs1230337744, COSV53129597; called by muse, mutect2, varscan2
- RNF145 | c.1035C>T p.I345= (on ENST00000424310 / NM_001199383.2; = p.I373= on NM_144726.2) | Silent (SNP) | VAF 15/67 reads (22%) | called by muse, mutect2, varscan2
- RPS6KA3 | c.423G>A p.G141= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV65388887; called by muse, mutect2, varscan2
- RRP12 | c.3189G>A p.E1063= | Silent (SNP) | VAF 31/101 reads (31%) | catalogued as rs1183838465, COSV59670167; called by muse, mutect2, varscan2
- SCN8A | c.2853C>T p.A951= | Silent (SNP) | VAF 82/198 reads (41%) | called by mutect2, varscan2
- SDE2 | c.537C>T p.S179= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs1285067280, COSV55252611; called by muse, mutect2, varscan2
- SERINC1 | c.1164C>T p.F388= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV60102578, COSV60102903; called by muse, mutect2, varscan2
- SFSWAP | c.627C>T p.H209= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs758703880, COSV55524443; called by mutect2, varscan2
- SIGLEC12 | c.1743G>A p.Q581= (on ENST00000291707 / NM_053003.4; = p.Q463= on NM_033329.2) | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV52463748, COSV99389649; called by muse, mutect2, varscan2
- SIGMAR1 | c.159C>T p.D53= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs1320347383, COSV52844884; called by muse, mutect2, varscan2
- SLC25A6 | c.384C>T p.L128= | Silent (SNP) | VAF 12/146 reads (8%) | catalogued as COSV67317920; called by muse, mutect2
- SLC2A11 | c.390C>T p.L130= (on ENST00000345044 / NM_001024938.4; = p.L137= on NM_030807.5) | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs775747841, COSV55393252; called by muse, mutect2, varscan2
- SLC36A3 | c.951C>T p.I317= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as COSV58857823; called by muse, mutect2, varscan2
- SLC38A1 | c.183G>A p.K61= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV67064346; called by muse, mutect2, varscan2
- SLC5A6 | c.750C>T p.P250= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV60160714; called by muse, mutect2, varscan2
- SLITRK3 | c.2724C>T p.P908= | Silent (SNP) | VAF 28/52 reads (54%) | called by muse, mutect2, varscan2
- SNTG2 | c.348C>T p.F116= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs370615639; called by muse, mutect2, varscan2
- SOWAHB | c.2196C>T p.F732= | Silent (SNP) | VAF 40/178 reads (22%) | catalogued as COSV57554281; called by muse, mutect2, varscan2
- SPATA31E1 | c.534G>A p.G178= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV57794023; called by muse, mutect2, varscan2
- SPIN2A | c.741C>T p.F247= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV66520665; called by muse, mutect2, varscan2
- SPTA1 | c.4693C>T p.L1565= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV63757353; called by muse, mutect2, varscan2
- SSUH2 | c.369C>T p.S123= | Silent (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- ST8SIA5 | c.540G>A p.R180= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV59330487, COSV59333971; called by muse, mutect2, varscan2
- SV2A | c.1956C>T p.I652= | Silent (SNP) | VAF 36/122 reads (30%) | catalogued as rs138258149; called by muse, mutect2, varscan2
- SYCP2L | c.1779T>G p.A593= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV51656187; called by muse, mutect2, varscan2
- TAMM41 | c.132G>A p.Q44= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV56072755; called by muse, mutect2, varscan2
- TDGF1 | c.39G>A p.V13= | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as COSV56127930; called by muse, mutect2, varscan2
- TELO2 | c.39G>A p.R13= | Silent (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- TENM4 | c.3222C>T p.V1074= | Silent (SNP) | VAF 18/43 reads (42%) | called by muse, mutect2, varscan2
- TMEM266 | c.966G>A p.T322= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as rs138438508; called by muse, mutect2, varscan2
- TRAV20 | c.72G>A p.Q24= | Silent (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- TRDV1 | c.273G>A p.A91= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs770320799, COSV66599431, COSV66599530; called by mutect2, varscan2
- TRPC3 | c.1290C>T p.A430= (on ENST00000379645 / NM_001366479.2; = p.A357= on NM_003305.2) | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV53378934; called by muse, mutect2, varscan2
- TTLL6 | c.1695G>A p.K565= (on ENST00000393382 / NM_001130918.3; = p.K258= on NM_173623.3) | Silent (SNP) | VAF 59/352 reads (17%) | catalogued as COSV64978441; called by muse, mutect2, varscan2
- VIPR2 | c.723C>T p.F241= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs1385818046, COSV51113676; called by muse, mutect2, varscan2
- VPS13B | c.7416C>T p.T2472= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV62152275; called by muse, mutect2, varscan2
- WDR25 | c.897G>A p.R299= | Silent (SNP) | VAF 28/121 reads (23%) | catalogued as rs1364148905, COSV58938756; called by muse, mutect2, varscan2
- XIRP2 | c.7008G>A p.R2336= (on ENST00000628543; = p.R2511= on NM_152381.6) | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV54701677; called by muse, mutect2, varscan2
- XKR3 | c.252C>T p.I84= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV58886152; called by muse, mutect2, varscan2
- ZAN | c.7314C>T p.T2438= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as rs756476991, COSV61813039; called by muse, mutect2, varscan2
- ZC3H7A | c.1212C>T p.F404= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV63270869; called by muse, mutect2, varscan2
- ZFPM2 | c.1449A>T p.P483= | Silent (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- ZIM3 | c.612C>T p.F204= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as rs758622269, COSV54139990; called by muse, mutect2, varscan2
- ANKRD33 | c.-357G>A | 5'UTR (SNP) | VAF 19/110 reads (17%) | catalogued as COSV56607769; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504645 T>A | 5'Flank (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- ARHGEF11 | c.4511-149C>T | Intron (SNP) | VAF 13/61 reads (21%) | catalogued as COSV100168093; called by muse, mutect2, varscan2
- COASY | c.-182C>T | 5'UTR (SNP) | VAF 18/74 reads (24%) | catalogued as rs753779026; called by muse, mutect2, varscan2
- COASY | c.-181C>T | 5'UTR (SNP) | VAF 18/75 reads (24%) | catalogued as rs754940764; called by muse, mutect2, varscan2
- NRP2 | c.2440+9504C>T | Intron (SNP) | VAF 25/65 reads (38%) | catalogued as rs368938118, COSV104381195; called by mutect2, varscan2
- RBMX | c.110-89G>C | Intron (SNP) | VAF 28/120 reads (23%) | catalogued as COSV100284452; called by muse, mutect2, varscan2
- SEZ6L | c.*1736G>A | 3'UTR (SNP) | VAF 8/75 reads (11%) | catalogued as COSV50669242; called by muse, mutect2, varscan2
- SNORD114-12 | n.30G>A | RNA (SNP) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- SSX9P | n.99G>A | RNA (SNP) | VAF 13/50 reads (26%) | catalogued as rs187170531; called by muse, mutect2, varscan2
